Somatic mutation profile of tumor specimen C3L-00813-01 (aliquot CPT0015810013) from CPTAC case C3L-00813, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.7 years (22,521 days).
Specimen C3L-00813-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bc1a672-8ff8-4149-8ad4-9b71b2c444fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00813-31 (Blood Derived Normal), aliquot CPT0018370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05f6a190-0e7d-4d16-a7a9-a2accca4dd4c

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Intron 6, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 87/391 reads (22%) | hotspot (GDC flag); catalogued as rs5030818, CM941381, CM961432, COSV56542817, COSV56554019, COSV56564848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPRS | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs1000887309; called by muse, mutect2, varscan2
- C5orf38 | c.404+8C>A | Splice Region (SNP) | VAF 55/305 reads (18%) | catalogued as COSV57410528; called by muse, mutect2, varscan2
- CSNK2A2 | c.430-7C>G | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as rs769939605; called by muse, mutect2, varscan2
- DYNC1H1 | c.6028C>G p.P2010A | Missense Mutation (SNP) | VAF 84/526 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100795591; called by muse, varscan2
- ENG | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs777633247, CM111598; called by muse, mutect2
- FAM47A | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV60500448; called by muse, mutect2, varscan2
- FEN1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 111/548 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs371695318; called by muse, mutect2, varscan2
- GPATCH1 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749564199; called by muse, mutect2, varscan2
- KDM4B | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs778616444; called by muse, mutect2, varscan2
- MAP3K14 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60923720; called by muse, mutect2, varscan2
- MITF | c.356A>G p.Q119R (on ENST00000448226 / NM_006722.3; = p.Q13R on NM_000248.4) | Missense Mutation (SNP) | VAF 81/462 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100096635; called by muse, mutect2, varscan2
- MRGPRG | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1292700875, COSV60040406; called by muse, mutect2, varscan2
- MYO16 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755855336; called by muse, mutect2, varscan2
- NAGA | c.486del p.E163Rfs*14 | Frame Shift Del (DEL) | VAF 76/320 reads (24%) | catalogued as COSV67169994; called by mutect2, pindel, varscan2
- PARS2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64883696; called by muse, mutect2
- PDILT | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1373532778, COSV56703412; called by muse, mutect2, varscan2
- PTGER4 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1286068637; called by muse, mutect2, varscan2
- SLC23A3 | c.1724G>A p.G575E (on ENST00000409878 / NM_001144889.2; = p.G458E on NM_144712.5) | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99841055; called by muse, mutect2, varscan2
- SLC30A8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV69974851; called by muse, mutect2
- ZFR2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs866891369; called by muse, mutect2, varscan2
- ADAT1 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- AK8 | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAP1 | c.216dup p.D73* | Frame Shift Ins (INS) | VAF 46/340 reads (14%) | called by mutect2, pindel, varscan2
- C1S | c.788C>A p.T263N | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, varscan2
- CAVIN1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 38/842 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2
- CDC42BPB | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CUX1 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 28/392 reads (7%) | called by muse, mutect2
- CXXC1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- ELOVL4 | c.737G>T p.W246L | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPHB6 | c.2634G>C p.E878D | Missense Mutation (SNP) | VAF 76/494 reads (15%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM181A | c.859_869del p.P287Gfs*155 | Frame Shift Del (DEL) | VAF 48/216 reads (22%) | called by mutect2, pindel
- FOXP2 | c.410A>C p.E137A | Missense Mutation (SNP) | VAF 104/614 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, varscan2
- GNPAT | c.57C>A p.S19R | Missense Mutation (SNP) | VAF 189/1054 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPGD | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 110/416 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IL20RA | c.1378del p.L460Wfs*114 | Frame Shift Del (DEL) | VAF 17/162 reads (10%) | called by mutect2, pindel
- KMT2E | c.3806C>G p.A1269G | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- LIN52 | c.318T>G p.I106M | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2
- LRP4 | c.1841G>A p.W614* | Nonsense Mutation (SNP) | VAF 75/878 reads (9%) | called by muse, mutect2
- MAP2K3 | c.645G>T p.L215F (on ENST00000342679 / NM_145109.3; = p.L186F on NM_002756.4) | Missense Mutation (SNP) | VAF 60/556 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MATR3 | c.2290G>C p.G764R | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NCEH1 | c.561_565del p.R188Sfs*8 (on ENST00000538775; = p.R148Sfs*8 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel
- NYAP2 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- P4HB | c.1429G>T p.G477W | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHA8 | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 260/1243 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- PHTF2 | c.747T>G p.D249E (on ENST00000248550 / NM_001366089.1; = p.D211E on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RAB4B | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RAVER1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- RNF111 | c.2498A>G p.Y833C | Missense Mutation (SNP) | VAF 6/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SERINC4 | c.321del p.S108Lfs*56 | Frame Shift Del (DEL) | VAF 57/230 reads (25%) | called by mutect2, pindel, varscan2
- SFSWAP | c.1790G>C p.R597P | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SVIL | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TGM5 | c.394del p.Q132Sfs*2 | Frame Shift Del (DEL) | VAF 132/637 reads (21%) | called by mutect2, pindel, varscan2
- TRAF3IP1 | c.1245_1246insTC p.T416Sfs*80 | Frame Shift Ins (INS) | VAF 45/310 reads (15%) | called by mutect2, pindel, varscan2
- ARCN1 | c.333T>C p.F111= | Silent (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- CACNG8 | c.729C>G p.L243= | Silent (SNP) | VAF 173/829 reads (21%) | called by muse, mutect2, varscan2
- CYP2B6 | c.1008C>A p.R336= | Silent (SNP) | VAF 46/443 reads (10%) | called by muse, mutect2, varscan2
- MTR | c.3138G>A p.L1046= | Silent (SNP) | VAF 76/328 reads (23%) | catalogued as COSV63963742; called by muse, mutect2, varscan2
- NCAPD3 | c.2385C>T p.I795= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs1223500368; called by muse, mutect2, varscan2
- NLRP3 | c.1362G>C p.G454= | Silent (SNP) | VAF 54/274 reads (20%) | catalogued as rs200314422, COSV60227159; called by muse, mutect2, varscan2
- NRBP1 | c.537T>G p.R179= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV51993736; called by muse, mutect2, varscan2
- SELE | c.597C>T p.N199= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs1269075678; called by muse, mutect2, varscan2
- SLC13A5 | c.54C>T p.F18= | Silent (SNP) | VAF 80/389 reads (21%) | called by muse, mutect2, varscan2
- TENM1 | c.7725C>T p.F2575= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV64424855; called by muse, mutect2, varscan2
- TGM2 | c.621C>T p.A207= | Silent (SNP) | VAF 109/510 reads (21%) | catalogued as rs770029921; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM208 | c.159C>T p.A53= | Silent (SNP) | VAF 36/238 reads (15%) | called by muse, mutect2, varscan2
- ZNF718 | c.1089A>C p.G363= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.836-990C>A | Intron (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- ASIC4 | c.1018+546C>A | Intron (SNP) | VAF 19/160 reads (12%) | catalogued as COSV61732393; called by muse, mutect2, varscan2
- ASIC4 | c.1018+547C>T | Intron (SNP) | VAF 17/156 reads (11%) | catalogued as COSV100761661; called by muse, mutect2, varscan2
- DYNC1I2 | c.245-52G>A | Intron (SNP) | VAF 22/158 reads (14%) | called by muse, mutect2, varscan2
- FAM117B | c.846+15del | Intron (DEL) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- GPR6 | chr6:109978740 G>C | 5'Flank (SNP) | VAF 31/181 reads (17%) | catalogued as rs1326946116; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23927C>T | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as COSV101042720; called by muse, mutect2, varscan2
